Somatic mutation profile of tumor specimen 0DQVID from CCDI case PBCFAS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 8.2 years (2,993 days).
Specimen 0DQVID: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25fb2f70-9aa6-4121-a3c5-5d01b62ca95f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQVIW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d0b8295-adf3-4640-8082-b9a9cbcdf412

The open-access MAF lists 84 somatic variants for this specimen: 46 protein-altering or splice-affecting, 17 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 17, Intron 10, 3'UTR 7, 5'UTR 4, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH9 | c.1828G>A p.G610S | Missense Mutation (SNP) | VAF 172/988 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.989); catalogued as rs764882241, COSV50263738; called by muse, mutect2, varscan2
- CORO7 | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 90/339 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773671001, COSV52033487; called by muse, mutect2, varscan2
- DOCK6 | c.3079C>T p.R1027W | Missense Mutation (SNP) | VAF 64/587 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs780826744, COSV53911636; called by muse, mutect2, varscan2
- FAM170A | c.942G>C p.W314C | Missense Mutation (SNP) | VAF 42/686 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV58926002; called by muse, mutect2
- FAM187B | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 68/475 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV61201662; called by muse, mutect2, varscan2
- FAT2 | c.5914G>A p.V1972I | Missense Mutation (SNP) | VAF 53/914 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1317663957; called by muse, mutect2
- FBXL4 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 74/604 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs763115531, COSV57749280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLYATL3 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 87/607 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1446417106; called by muse, mutect2, varscan2
- HERC6 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 110/404 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369219414; called by muse, mutect2, varscan2
- HYDIN | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 75/516 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs113898693, COSV55479229; called by muse, mutect2, varscan2
- MAP3K10 | c.1871G>A p.S624N | Missense Mutation (SNP) | VAF 66/477 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1228729806; called by muse, mutect2, varscan2
- MYOM3 | c.3998G>A p.R1333H | Missense Mutation (SNP) | VAF 91/524 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs559271802, COSV58393169; called by muse, mutect2, varscan2
- NCAPD3 | c.3746C>T p.A1249V | Missense Mutation (SNP) | VAF 253/598 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1231520595; called by muse, mutect2, varscan2
- PTK6 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 114/820 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53917990, COSV99420668; called by muse, mutect2, varscan2
- RORC | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 374/679 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs746187982, COSV104402616; called by muse, mutect2, varscan2
- RYR2 | c.3659A>G p.D1220G | Missense Mutation (SNP) | VAF 335/682 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV63695101; called by muse, mutect2, varscan2
- TMEM25 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 181/499 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs782802854; called by muse, mutect2, varscan2
- UBE2J1 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 53/834 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs761994024, COSV70561125; called by muse, mutect2
- WNT9A | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 154/527 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs1157437166, COSV55293789; called by muse, mutect2, varscan2
- ZFPM2 | c.3013G>C p.E1005Q | Missense Mutation (SNP) | VAF 54/1160 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.285); catalogued as COSV65875280; called by muse, mutect2
- AK4 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 165/795 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANKS1B | c.2558T>C p.L853S (on ENST00000547776 / NM_152788.4; = p.L79S on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/535 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ANO3 | c.2273T>C p.M758T | Missense Mutation (SNP) | VAF 114/667 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- APC2 | c.2213C>T p.A738V | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- BCAT1 | c.494C>A p.T165K | Missense Mutation (SNP) | VAF 48/339 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 30/1032 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CEACAM19 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 58/780 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2
- CLIC1 | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 160/876 reads (18%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CLK3 | c.1873C>A p.P625T (on ENST00000395066 / NM_001130028.1; = p.P477T on NM_003992.4) | Missense Mutation (SNP) | VAF 109/485 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSMD1 | c.3634+1G>C p.X1212_splice (on ENST00000520002; = p.X1211_splice on NM_033225.6) | Splice Site (SNP) | VAF 114/766 reads (15%) | called by muse, mutect2, varscan2
- DAPK1 | c.1011G>T p.L337= | Splice Region (SNP) | VAF 91/477 reads (19%) | called by muse, mutect2, varscan2
- DLGAP3 | c.895T>A p.L299M | Missense Mutation (SNP) | VAF 90/586 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EIF3B | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 394/1590 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- F5 | c.3229T>A p.S1077T | Missense Mutation (SNP) | VAF 36/974 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.053); called by muse, mutect2
- FANCM | c.6119A>T p.N2040I | Missense Mutation (SNP) | VAF 26/674 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); called by muse, mutect2
- FEZF1 | c.128C>G p.P43R | Missense Mutation (SNP) | VAF 26/814 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ING3 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 146/1734 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- LRP12 | c.1379dup p.N460Kfs*7 | Frame Shift Ins (INS) | VAF 326/810 reads (40%) | called by mutect2, varscan2
- NEUROD4 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 222/650 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.952); called by mutect2, varscan2
- REV3L | c.7306A>G p.K2436E | Missense Mutation (SNP) | VAF 116/569 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, varscan2
- RSAD2 | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 28/727 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC26A8 | c.1978C>T p.Q660* | Nonsense Mutation (SNP) | VAF 40/1174 reads (3%) | called by muse, mutect2
- SLC6A5 | c.1931T>C p.I644T | Missense Mutation (SNP) | VAF 50/564 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2
- SOCS5 | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 336/810 reads (41%) | called by mutect2, varscan2
- TAAR8 | c.272G>T p.R91M | Missense Mutation (SNP) | VAF 126/876 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, varscan2
- TCF19 | c.776A>G p.K259R | Missense Mutation (SNP) | VAF 43/584 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2
- CCDC102B | c.648G>A p.E216= | Silent (SNP) | VAF 24/846 reads (3%) | called by muse, mutect2
- CNBD1 | c.648T>C p.N216= | Silent (SNP) | VAF 283/1242 reads (23%) | called by muse, mutect2, varscan2
- FZD10 | c.525C>T p.H175= | Silent (SNP) | VAF 24/340 reads (7%) | called by muse, mutect2
- GZMH | c.588C>A p.T196= | Silent (SNP) | VAF 137/350 reads (39%) | catalogued as rs751202637, COSV99361935; called by muse, mutect2, varscan2
- HLA-DMB | c.18G>A p.P6= | Silent (SNP) | VAF 169/742 reads (23%) | called by muse, mutect2, varscan2
- LRRC37A3 | c.4365C>T p.S1455= | Silent (SNP) | VAF 63/642 reads (10%) | catalogued as COSV100140914; called by muse, mutect2, varscan2
- LRRC74A | c.147C>G p.A49= | Silent (SNP) | VAF 262/681 reads (38%) | catalogued as rs773818563, COSV53609826; called by muse, mutect2, varscan2
- MGAM2 | c.7503A>C p.A2501= | Silent (SNP) | VAF 34/1192 reads (3%) | catalogued as rs1175986978; called by muse, mutect2
- NUP210 | c.246G>T p.V82= | Silent (SNP) | VAF 141/613 reads (23%) | called by muse, mutect2, varscan2
- PLXNA2 | c.2658C>T p.D886= | Silent (SNP) | VAF 183/607 reads (30%) | called by muse, mutect2, varscan2
- RTL4 | c.348T>A p.P116= | Silent (SNP) | VAF 262/329 reads (80%) | catalogued as COSV61205655; called by muse, mutect2, varscan2
- TOE1 | c.540A>T p.L180= | Silent (SNP) | VAF 60/920 reads (7%) | called by muse, mutect2
- TRIM50 | c.1416G>A p.P472= | Silent (SNP) | VAF 27/1093 reads (2%) | catalogued as rs1256013179; called by muse, mutect2
- TRPV1 | c.2127G>A p.T709= | Silent (SNP) | VAF 50/746 reads (7%) | catalogued as rs200130650, COSV51517243, COSV99439917, COSV99441019; called by muse, mutect2
- UBAP1L | c.414C>A p.P138= | Silent (SNP) | VAF 47/142 reads (33%) | called by muse, mutect2, varscan2
- ZNF83 | c.189C>A p.V63= | Silent (SNP) | VAF 188/755 reads (25%) | called by muse, mutect2, varscan2
- ZNF865 | c.1416G>A p.A472= | Silent (SNP) | VAF 92/359 reads (26%) | catalogued as rs751407912; called by muse, mutect2, varscan2
- AASS | c.-35T>A | 5'UTR (SNP) | VAF 27/914 reads (3%) | called by muse, mutect2
- ACADSB | c.*52C>T | 3'UTR (SNP) | VAF 168/266 reads (63%) | catalogued as rs768243038; called by muse, mutect2, varscan2
- ALPK2 | c.1963-97A>G | Intron (SNP) | VAF 16/70 reads (23%) | catalogued as COSV64497478; called by muse, mutect2
- BMT2 | c.*42A>C | 3'UTR (SNP) | VAF 35/1106 reads (3%) | called by muse, mutect2
- DOCK4 | c.*54G>C | 3'UTR (SNP) | VAF 78/930 reads (8%) | called by muse, mutect2
- HDLBP | c.*23C>G | 3'UTR (SNP) | VAF 20/230 reads (9%) | catalogued as COSV51470641; called by muse, mutect2
- IL1RN | c.*3C>T | 3'UTR (SNP) | VAF 66/371 reads (18%) | called by muse, mutect2, varscan2
- LUZP2 | c.397-13286A>G | Intron (SNP) | VAF 14/346 reads (4%) | called by muse, mutect2
- MAP7D1 | c.1887-14G>T | Intron (SNP) | VAF 28/768 reads (4%) | catalogued as rs961555102; called by muse, mutect2
- NUDT13 | c.592-23_592-22del | Intron (DEL) | VAF 28/129 reads (22%) | called by mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 18/156 reads (12%) | called by muse, varscan2
- RNF152 | c.-9C>T | 5'UTR (SNP) | VAF 82/215 reads (38%) | catalogued as rs189095456; called by muse, mutect2, varscan2
- SERINC5 | c.986+41T>C | Intron (SNP) | VAF 18/383 reads (5%) | catalogued as rs1189656758; called by muse, mutect2
- SNX14 | c.1109-24C>A | Intron (SNP) | VAF 24/299 reads (8%) | called by muse, mutect2
- TBX1 | c.512+38C>A | Intron (SNP) | VAF 88/185 reads (48%) | called by muse, mutect2, varscan2
- TRPV6 | c.1406+13C>A | Intron (SNP) | VAF 66/756 reads (9%) | called by muse, mutect2
- UBE2QL1 | c.*47C>G | 3'UTR (SNP) | VAF 75/197 reads (38%) | called by muse, mutect2, varscan2
- UFL1 | c.-20C>T | 5'UTR (SNP) | VAF 30/326 reads (9%) | called by muse, mutect2
- USP6 | c.156-11T>G | Intron (SNP) | VAF 32/227 reads (14%) | called by muse, mutect2, varscan2
- WTIP | c.*77G>A | 3'UTR (SNP) | VAF 59/293 reads (20%) | called by muse, mutect2, varscan2
- ZGPAT | c.1052-71C>T | Intron (SNP) | VAF 32/173 reads (18%) | called by muse, mutect2
